Gene-level copy-number profile of tumor specimen TCGA-MF-A522-01A from TCGA case TCGA-MF-A522, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 54.9 years (20,051 days).
Specimen TCGA-MF-A522-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.01070b8e-c267-44cf-88f7-497c72bf03ab.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 3,904 have no estimate.
https://portal.gdc.cancer.gov/files/0f4ec9ad-a7f9-40ae-81f6-24500a92e3be

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 221; copy number 2: 1,316; copy number 3: 4,751; copy number 4: 17,619; copy number 5: 7,026; copy number 6: 12,945; copy number 7: 12,833.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MF-A522-01A-11D-A25M-01): tumor purity 0.64, ploidy 5.45, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,167,357, 1 gene: RNU6-904P.
- chr8:213,186–264,703, 6 genes: RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2.
- chr8:14,161,084–14,165,359, 1 gene: AC022039.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 221. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
